CCDI case PBCNTL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b4204f17-51ff-43b7-941c-89af79a24fb0

Demographics
Sex at birth: female.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 10.8 years (3,929 days).

Biospecimens (3 samples)
- Sample 0DW72P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW72Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
